Somatic mutation profile of tumor specimen TCGA-KC-A7FE-01A (aliquot TCGA-KC-A7FE-01A-12D-A33T-08) from TCGA case TCGA-KC-A7FE, project TCGA-PRAD (Prostate Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Prostate gland; Age at diagnosis: 62.2 years (22,718 days).
Specimen TCGA-KC-A7FE-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 3fed2765-f193-46d0-92b8-d1f6ec54a634.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-KC-A7FE-10A (Blood Derived Normal), aliquot TCGA-KC-A7FE-10A-01D-A33W-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/3b12b89b-4e1e-4957-b771-a741d555667a

The open-access MAF lists 4 somatic variants for this specimen: 4 protein-altering or splice-affecting.
By variant classification: Missense Mutation 4.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CD48 | c.436G>A p.D146N | Missense Mutation (SNP) | VAF 22/125 reads (18%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100924195; called by muse, mutect2, varscan2
- EGFLAM | c.2393G>A p.S798N | Missense Mutation (SNP) | VAF 3/29 reads (10%) | SIFT tolerated (0.1); PolyPhen benign (0.276); catalogued as COSV100379903; called by muse, mutect2
- METTL4 | c.1297C>G p.P433A | Missense Mutation (SNP) | VAF 8/91 reads (9%) | SIFT tolerated (0.18); PolyPhen benign (0.247); catalogued as COSV100170484; called by muse, mutect2
- PNISR | c.1060A>C p.I354L | Missense Mutation (SNP) | VAF 8/59 reads (14%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.953); catalogued as COSV100984311; called by muse, mutect2, varscan2
